Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A193, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A193-06A (Metastatic).

ICD-0-3.

Melanoma, NOS

8720/3

12/14/10

lw

PATIENT HISTORY:

Not given.

PRE-OP DIAGNOSIS: Melanoma.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Excision melanoma-right forearm, right neck and axilla.

Site: Soft tissue - neck
c49.0

FINAL DIAGNOSIS:

PART 1: SKIN, RIGHT FOREARM LESION, EXCISION -
INFUNDIBULAR CYST.

PART 2

AND 3: LYMPH NODE AND SOFT TISSUE, RIGHT NECK MASS, EXCISION -
A. METASTATIC MELANOMA IN LYMPH NODES AND SOFT TISSUE.
B. MELANOPHAGES IN ONE LYMPH NODE.

COMMENT:

The tumor appears mostly viable. Individual nodules show foci of necrosis ranging from 5-20%. One nodule in the chest wall contains only necrotic tissue with abundant melanin. Tumor infiltrating lymphocytes are scant to absent. A total of six lymph nodes are present in the specimen which are negative for tumor.

Mt/AA Discrepancy		X

Source: NCI Genomic Data Commons file 4046553c-a32a-4d27-aa7f-9662516ed021 (TCGA-ER-A193.DCC32120-A9D1-424C-A2BE-1FA2F77962F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).